Somatic mutation profile of tumor specimen TCGA-PG-A915-01A (aliquot TCGA-PG-A915-01A-11D-A37N-09) from TCGA case TCGA-PG-A915, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.6 years (22,119 days).
Specimen TCGA-PG-A915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 858b4fea-a0b5-42e3-9c92-cdd942716f7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PG-A915-10A (Blood Derived Normal), aliquot TCGA-PG-A915-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91f1f0c6-32f1-4076-a158-e4023a49b52f

The open-access MAF lists 69 somatic variants for this specimen: 58 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 10, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs587776932, CM126694, COSV55930478, COSV55944375; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59042523, COSV59042723; called by muse, mutect2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 22/22 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.8876A>G p.K2959R | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99947825; called by muse, mutect2, varscan2
- ANKS1B | c.1098A>C p.E366D | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV100246009; called by muse, mutect2, varscan2
- BDP1 | c.6749C>T p.T2250I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV100703182; called by muse, mutect2, varscan2
- CCDC39 | c.2219A>C p.Y740S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99869188; called by muse, mutect2, varscan2
- CD1A | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99192405; called by muse, mutect2, varscan2
- CDC7 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99319766; called by muse, mutect2, varscan2
- CDH10 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100051745; called by muse, mutect2, varscan2
- DNAH7 | c.9821T>A p.L3274H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415513; called by muse, mutect2, varscan2
- DNAJC10 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as rs1025974432, COSV99899328; called by muse, mutect2, varscan2
- DPPA3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100559921, COSV61503207; called by muse, mutect2, varscan2
- DPYD | c.1041T>G p.C347W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929182; called by muse, mutect2
- FKBP6 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99334005; called by muse, mutect2, varscan2
- FRMD4B | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 50/80 reads (63%) | catalogued as rs775396961, COSV101273416, COSV68329261; called by muse, mutect2, varscan2
- FRMPD3 | c.965G>C p.R322P | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346417, COSV99346980; called by muse, mutect2, varscan2
- FTCD | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52429053; called by muse, mutect2, varscan2
- GABRA6 | c.812C>G p.A271G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99194570; called by muse, mutect2
- GBF1 | c.2433+2T>C p.X811_splice (on ENST00000369983 / NM_001377137.1; = p.X810_splice on NM_004193.3) | Splice Site (SNP) | VAF 10/117 reads (9%) | catalogued as COSV100890514; called by muse, mutect2
- GHRL | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs372434370, COSV55055864; called by muse, mutect2, varscan2
- HCN1 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1477444033, COSV100301983, COSV57520811; called by muse, mutect2, varscan2
- HS3ST5 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.699); catalogued as COSV100451004; called by muse, mutect2, varscan2
- IDI2 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV52986935; called by muse, mutect2, varscan2
- KIF1B | c.3563C>T p.P1188L (on ENST00000377086 / NM_001365952.1; = p.P1142L on NM_015074.3) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99823481; called by muse, mutect2
- KPNA5 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754741368, COSV62653677; called by muse, mutect2, varscan2
- L3MBTL3 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100696197; called by muse, mutect2, varscan2
- LAMA1 | c.6931G>T p.D2311Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101056592, COSV101056983; called by muse, mutect2, varscan2
- LYST | c.9053G>A p.R3018Q | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as rs367792096; called by muse, mutect2, varscan2
- NLGN3 | c.1795C>T p.R599* (on ENST00000358741 / NM_181303.2; = p.R579* on NM_018977.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/53 reads (91%) | catalogued as rs866980980, COSV100704816; called by muse, mutect2, varscan2
- OR1A1 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs994929821, COSV100410785; called by muse, mutect2, varscan2
- POSTN | c.2315C>G p.T772R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.174); catalogued as COSV101123357; called by mutect2, varscan2
- PPFIA2 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV100333776, COSV61052166; called by muse, mutect2, varscan2
- PPIL1 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV101033881; called by muse, mutect2, varscan2
- PTPRD | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.982); catalogued as COSV100645038, COSV61926901; called by muse, mutect2, varscan2
- PUM1 | c.3281G>A p.R1094H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99928172; called by muse, mutect2, varscan2
- RCBTB2 | c.677T>A p.V226D | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100749595; called by muse, mutect2, varscan2
- RIPK2 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99609908; called by muse, mutect2
- RNF138 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs778679208, COSV99857520; called by muse, mutect2, varscan2
- SERPINI2 | c.713A>T p.E238V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99248006; called by muse, mutect2, varscan2
- SKI | c.529A>C p.I177L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101049428; called by muse, mutect2
- SLC15A1 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100919493; called by muse, mutect2, varscan2
- SLC22A7 | c.1021C>T p.P341S (on ENST00000372585 / NM_153320.2; = p.P339S on NM_006672.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as COSV99240375; called by muse, mutect2, varscan2
- SLC7A6 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99546601; called by muse, mutect2, varscan2
- SNX17 | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs751127777, COSV99277649; called by muse, mutect2, varscan2
- STAB2 | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201505244, COSV101186013; called by muse, mutect2, varscan2
- TAF5 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100428263; called by muse, mutect2
- TTC21A | c.2602C>G p.R868G | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100086845, COSV100087368; called by muse, mutect2, varscan2
- USP6NL | c.452C>G p.T151R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99509717; called by muse, mutect2
- YIPF3 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.482); catalogued as rs751211124, COSV58305991; called by muse, varscan2
- ZFHX4 | c.7522T>C p.W2508R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99263462; called by muse, mutect2
- ZMAT5 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99334818; called by muse, mutect2
- ZNF761 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV100483395; called by muse, mutect2, varscan2
- ZWINT | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100571518; called by muse, varscan2
- ARID5B | c.1376del p.P459Qfs*20 | Frame Shift Del (DEL) | VAF 14/21 reads (67%) | called by mutect2, varscan2
- CNGA4 | c.814_822dup p.M272_T274dup | In Frame Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- COL3A1 | c.24del p.S9Afs*57 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- UGT2B4 | c.1172del p.V391Gfs*16 | Frame Shift Del (DEL) | VAF 37/120 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.1920C>T p.D640= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs550683309, COSV100941629; called by muse, mutect2, varscan2
- DBN1 | c.1410C>T p.P470= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs374007032, COSV99446078; called by muse, mutect2, varscan2
- ISYNA1 | c.1554T>A p.V518= | Silent (SNP) | VAF 44/336 reads (13%) | catalogued as COSV99526126; called by muse, mutect2, varscan2
- MGAM | c.2262G>A p.V754= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs777867278, COSV101527528; called by muse, mutect2, varscan2
- MROH2B | c.1056C>T p.I352= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1193067458, COSV68181714; called by muse, mutect2
- NRROS | c.732C>G p.T244= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs1241924067, COSV100145507, COSV60748517; called by muse, mutect2, varscan2
- OR14K1 | c.603G>C p.G201= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99315249; called by muse, mutect2, varscan2
- OR2T6 | c.48G>T p.G16= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV63216090; called by mutect2, varscan2
- PRAC1 | c.9C>T p.C3= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV51704882, COSV99284881; called by muse, mutect2
- SYNJ1 | c.828G>A p.V276= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs780954414, COSV100449357; called by muse, mutect2, varscan2
- FOXP2 | c.258+36118A>C | Intron (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100646797; called by muse, mutect2, varscan2
